Somatic mutation profile of tumor specimen TCGA-L5-A8NN-01A (aliquot TCGA-L5-A8NN-01A-11D-A37C-09) from TCGA case TCGA-L5-A8NN, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 81.8 years (29,891 days).
Specimen TCGA-L5-A8NN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15e50ce0-2ebe-4c7c-a636-eecee5b1340d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NN-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NN-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50eee23d-4ad4-48d2-b199-c3aaf26da131

The open-access MAF lists 114 somatic variants for this specimen: 82 protein-altering or splice-affecting, 26 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 26, Nonsense Mutation 6, Frame Shift Del 4, Intron 3, RNA 2, Nonstop Mutation 1, Frame Shift Ins 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2977A>C p.K993Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as CD160907, CM056294, COSV57326945, COSV57371737; called by muse, mutect2, varscan2
- ARHGAP45 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1304006735, COSV57430711; called by muse, mutect2, varscan2
- BIRC2 | c.1022G>A p.G341D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778451362; called by muse, mutect2, varscan2
- CMTM5 | c.556G>T p.A186S (on ENST00000339180 / NM_001288746.2; = p.A119S on NM_138460.3) | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.38); catalogued as COSV59307028; called by muse, mutect2, varscan2
- CNGA3 | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as rs1386641968, CM147381, COSV55627611; called by muse, mutect2
- COL6A1 | c.1979C>T p.A660V | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs748997622, COSV62612294; called by muse, mutect2
- DLX3 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762788082, COSV71547303; called by muse, mutect2, varscan2
- EDC4 | c.4074G>T p.M1358I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as rs1266762389; called by muse, mutect2, varscan2
- IFT140 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as rs538562131; called by mutect2, varscan2
- INTS4 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1328556664; called by muse, mutect2, varscan2
- JAG2 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1233996748; called by muse, mutect2, varscan2
- KRT34 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs374681338; called by muse, mutect2, varscan2
- MUC5B | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs754603108; called by muse, mutect2, varscan2
- NEK11 | c.1669C>G p.P557A | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV67287122; called by muse, mutect2, varscan2
- NTRK1 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs765477124, COSV62324118; called by muse, mutect2, varscan2
- PCDH18 | c.2224A>T p.T742S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0.033); catalogued as rs1331539870; called by muse, mutect2, varscan2
- PCDHB3 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 114/199 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs1187516146, COSV50576892; called by muse, mutect2, varscan2
- PIK3CG | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs749714535; called by muse, mutect2, varscan2
- PLXNA1 | c.5086G>A p.D1696N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs1471458213; called by muse, mutect2
- PREX2 | c.3136C>G p.Q1046E | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV55762161; called by muse, mutect2, varscan2
- RB1 | c.2391dup p.R798Tfs*17 | Frame Shift Ins (INS) | VAF 34/63 reads (54%) | catalogued as CI012716, COSV57300252, COSV57321960; called by mutect2, pindel, varscan2
- RDH10 | c.597G>T p.L199F | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as COSV53584576; called by muse, mutect2, varscan2
- RSC1A1 | c.1787G>C p.R596P | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as COSV60779102; called by muse, mutect2, varscan2
- SCN9A | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.072); catalogued as COSV57620134; called by muse, mutect2
- SLC12A4 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.411); catalogued as rs755501835, COSV50455132; called by muse, varscan2
- SLC22A1 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as rs760315741, COSV100266738, COSV61452511; called by muse, mutect2, varscan2
- STOX2 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1225723250, COSV57852746; called by muse, mutect2, varscan2
- TOGARAM2 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs141303160; called by muse, mutect2, varscan2
- UCKL1 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs773397582; called by muse, mutect2, varscan2
- WFDC9 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as rs867937693; called by muse, mutect2, varscan2
- ZCCHC8 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1419238938; called by muse, mutect2, varscan2
- ZNF285 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.022); catalogued as rs372788610; called by muse, mutect2, varscan2
- AHSP | c.11T>A p.L4H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- ALOX5AP | c.484T>A p.*162Kext*12 | Nonstop Mutation (SNP) | VAF 38/58 reads (66%) | called by muse, mutect2, varscan2
- ARID2 | c.590del p.P197Lfs*18 | Frame Shift Del (DEL) | VAF 18/28 reads (64%) | called by mutect2, pindel, varscan2
- ATXN3 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.147); called by muse, mutect2
- BIVM-ERCC5 | c.662C>A p.S221Y | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTAF1 | c.4837G>A p.A1613T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- CA11 | c.583A>C p.N195H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CASP6 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- CHGA | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CTNND1 | c.2065C>T p.Q689* (on ENST00000399050 / NM_001085458.2; = p.Q683* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- CYP2S1 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DZIP3 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- ELMO1 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- EPHB3 | c.2771A>G p.Y924C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); called by muse, mutect2
- EXOSC2 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FAP | c.2224A>T p.N742Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXO34 | c.1030G>A p.G344R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FRYL | c.3278G>A p.R1093K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- FZD2 | c.1141G>T p.A381S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GPR137B | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- HARS1 | c.71A>C p.Q24P | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- HNF4A | c.526A>C p.I176L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- IREB2 | c.44A>G p.E15G | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JMJD1C | c.3397C>G p.P1133A | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KMT2E | c.5024A>G p.H1675R | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KMT2E | c.5025C>A p.H1675Q | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- LRP1B | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- LRRIQ1 | c.2855G>T p.C952F | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC13 | c.581_612del p.T194Ifs*7 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel
- MUC17 | c.1794C>G p.N598K | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEO1 | c.3856C>A p.P1286T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- NES | c.3886C>A p.P1296T | Missense Mutation (SNP) | VAF 52/72 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- NPHS1 | c.2805del p.V936Sfs*12 | Frame Shift Del (DEL) | VAF 10/79 reads (13%) | called by mutect2, pindel, varscan2
- NTMT1 | c.379_388del p.D127Tfs*2 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- OR1Q1 | c.472C>A p.L158M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2
- PRDM15 | c.1401C>A p.C467* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- RPS14 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCRIB | c.311G>T p.C104F | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETD4 | c.1254G>T p.W418C | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- SLC5A2 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLITRK5 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SMG8 | c.1536G>C p.Q512H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SPTA1 | c.3409A>T p.I1137F | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- STAG2 | c.288+2dup p.X96_splice | Splice Site (INS) | VAF 47/69 reads (68%) | called by mutect2, pindel, varscan2
- SYNJ1 | c.3595G>A p.A1199T | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TRMO | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 78/122 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TSC2 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBQLN3 | c.588T>A p.H196Q | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZMYM3 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZNF442 | c.529G>T p.G177* | Nonsense Mutation (SNP) | VAF 48/68 reads (71%) | called by muse, varscan2
- ANO5 | c.1362G>A p.T454= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs747933251; called by muse, mutect2, varscan2
- BACH1 | c.2046C>T p.P682= | Silent (SNP) | VAF 5/16 reads (31%) | called by mutect2, varscan2
- COL14A1 | c.2472A>G p.G824= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- CRYBG2 | c.3330C>T p.T1110= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs369164243; called by muse, mutect2, varscan2
- DNAH5 | c.2817G>A p.T939= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs1338338371, COSV54208903; called by muse, mutect2, varscan2
- HYOU1 | c.2445C>G p.R815= | Silent (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.1779C>T p.A593= | Silent (SNP) | VAF 45/64 reads (70%) | catalogued as rs368495685, COSV100145417; called by muse, mutect2, varscan2
- KBTBD12 | c.660C>T p.V220= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- KIF3B | c.678C>T p.S226= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs751501042; called by muse, mutect2, varscan2
- LMOD2 | c.822C>T p.N274= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs764088293, COSV71755484; called by muse, mutect2, varscan2
- MARCHF4 | c.1003C>A p.R335= | Silent (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- MDGA1 | c.645G>A p.Q215= | Silent (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- METRNL | c.900G>A p.E300= | Silent (SNP) | VAF 54/146 reads (37%) | called by muse, mutect2, varscan2
- MFAP1 | c.336G>A p.V112= | Silent (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- MYBPC3 | c.3771C>T p.N1257= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as CM132382; called by mutect2, varscan2
- MYH6 | c.2541G>A p.T847= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs774131751, COSV62451841; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH8 | c.3394C>A p.R1132= | Silent (SNP) | VAF 33/56 reads (59%) | called by muse, mutect2, varscan2
- OR4P4 | c.825C>A p.I275= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100111495; called by muse, mutect2, varscan2
- PCDHB8 | c.1257C>T p.N419= | Silent (SNP) | VAF 69/335 reads (21%) | called by muse, mutect2, varscan2
- PDLIM5 | c.1482G>A p.L494= | Silent (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- PLCB2 | c.555C>T p.L185= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV53038866; called by muse, varscan2
- PTPRN2 | c.2427C>T p.H809= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs140246794; ClinVar: likely benign; called by muse, mutect2, varscan2
- PZP | c.4071T>G p.T1357= | Silent (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- SAMD9L | c.1146A>G p.E382= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- SCRIB | c.312C>T p.C104= | Silent (SNP) | VAF 19/80 reads (24%) | called by muse, mutect2, varscan2
- TRPC3 | c.489C>T p.T163= (on ENST00000379645 / NM_001366479.2; = p.T90= on NM_003305.2) | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs200026421; called by muse, varscan2
- AGAP3 | c.1021-1048T>C | Intron (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- DCHS2 | n.5042G>T | RNA (SNP) | VAF 9/34 reads (26%) | catalogued as COSV61770118; called by muse, mutect2, varscan2
- GNA12 | c.310-19741G>A | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as rs1216916048; called by muse, mutect2
- PALM2AKAP2 | c.400+6874C>T | Intron (SNP) | VAF 16/29 reads (55%) | catalogued as rs1300930077; called by muse, mutect2, varscan2
- PRR34 | n.327G>T | RNA (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- TGIF1 | c.-236C>T | 5'UTR (SNP) | VAF 39/82 reads (48%) | called by muse, mutect2, varscan2
